Somatic mutation profile of tumor specimen TCGA-EL-A3CO-01A (aliquot TCGA-EL-A3CO-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-EL-A3CO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60823e8a-8e80-4b52-88a8-7ac0bb61a5a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CO-10A (Blood Derived Normal), aliquot TCGA-EL-A3CO-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a12b5ff9-5b01-4d81-8309-4ac560ed99ae

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 16/79 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63309275, COSV63309367; called by muse, mutect2, varscan2
- AFM | c.880T>G p.S294A | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV56919050; called by muse, mutect2
- KCNMA1 | c.541-1G>A p.X181_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV54228596; called by muse, mutect2
- SYNE2 | c.19070A>G p.E6357G | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59940116; called by muse, mutect2
- BACH1 | c.871del p.T291Rfs*16 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, varscan2
- HECTD1 | c.4580C>A p.P1527H | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
